Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A267, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A267-06A (Metastatic).

1CD-0-3

Melanoma, malignant, NOS 8720/3

Site: lymph node, axillary C97.3

hw 4/27/11

SPECIMENS:

A. LEFT AXILLARY METASTATIC MELANOMA

SPECIMEN(S):

A. LEFT AXILLARY METASTATIC MELANOMA

GROSS DESCRIPTION:

A. LEFT AXILLARY METASTATIC MELANOMA

Received fresh is a 6 x 4 x 3.3-cm piece yellow-tan soft tissue, containing a firm flesh colored lymph node, 2.8 x 2.4 x 2.4 cm and a 0.3-cm lymph node. Portion of the larger lymph node is submitted for tissue procurement. Representative sections are submitted as follows:

A1-A2: remainder of large lymph node

A3: small lymph node

DIAGNOSIS:

A. LEFT AXILLARY METASTATIC MELANOMA, EXCISION:

- METASTATIC MALIGNANT MELANOMA IN TWO LYMPH NODES WITH EXTRANODAL SOFT TISSUE EXTENSION, SEE NOTE.

NOTE - The large positive lymph node measures 2.8x 2.4 cm.

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Metastatic melanoma

Gross Dictation:., Pathologist,

Microscopic/Diagnostic Dictation: Pathologist,

Final Review: Pathologist,

Final Review: Pathologist,

Final: Pathologist,

IPSA Discrepancy		/
See Synchronicity Summary Notes		/

Source: NCI Genomic Data Commons file a4c70606-6a90-4945-95b5-d3eedef739ba (TCGA-GN-A267.410A571A-0EA2-496D-9F1F-B99834338C52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).